Somatic mutation profile of tumor specimen BA2762D (aliquot aq-BA2762D) from BEATAML1.0 case 2061, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.7 years (8,274 days).
Specimen BA2762D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90663dd6-e0af-460f-9b27-528b0126c629.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2130D (Solid Tissue Normal), aliquot aq-BA2130D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdeab35f-0d50-45df-8c86-96278c40e98b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1791_1808dup p.K602_W603insCEYDLK | In Frame Ins (INS) | VAF 45/148 reads (30%) | catalogued as COSV54051484; called by mutect2, varscan2
- KIF26A | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs769390689, COSV100181234, COSV59466720; called by mutect2, varscan2
- ELAPOR1 | c.2830C>A p.L944M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPNT | c.1513G>C p.G505R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- NSD1 | c.7556C>A p.A2519E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- PAX1 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCBTB1 | c.1035C>T p.L345= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV51637389; called by muse, mutect2, varscan2
- TMEM212 | c.504C>A p.I168= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
